Gene-level copy-number profile of tumor specimen TCGA-86-7953-01A from TCGA case TCGA-86-7953, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.3 years (25,315 days).
Specimen TCGA-86-7953-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.216febf0-ffba-4d40-8591-7b05d61d52c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-7953-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bf8518b9-4933-4d58-8a5d-c44625f3d58d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 101; copy number 1: 20,489; copy number 2: 35,899; copy number 3: 2,163; copy number 4: 1,048; copy number 5: 45; copy number 6: 27; copy number 9: 23; copy number 10: 3; copy number 11: 5; copy number 17: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-7953-01A-11D-2183-01): tumor purity 0.35, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 101 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:83,643,602–83,815,263, 3 genes: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr14:60,396,469–65,102,695, 98 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 117 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:233,833,416–234,224,514, 10 genes, copy number 6 (within-gene range 4–6): HJURP, MSL3P1, AC005538.2, TRPM8, AC005538.1, AC005538.3, SPP2, AC006037.2, AC006037.1, AC122134.1.
- chr6:46,492,052–47,697,797, 20 genes, copy number 6–9 (within-gene range 3–9): AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2.
- chr11:33,665,220–35,838,523, 45 genes, copy number 5: AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2.
- chr19:29,268,976–32,072,113, 42 genes, copy number 9–17 (within-gene range 1–17): AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837.

Autosomal genes at a single copy (total copy number 1): 20,310. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
